Gene-level copy-number profile of tumor specimen TCGA-90-7767-01A from TCGA case TCGA-90-7767, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.2 years (20,534 days).
Specimen TCGA-90-7767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.abfe289b-4ece-421d-a516-ddc03dd0b7aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-90-7767-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4d90cac-f1fe-4df6-9ffe-df9f6fd8c1a0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,015; copy number 2: 22,641; copy number 3: 20,775; copy number 4: 5,341; copy number 5: 5,669; copy number 6: 1,162; copy number 7: 177; copy number 8: 32; copy number 13: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-90-7767-01A-11D-2121-01): tumor purity 0.54, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:35,599,732–35,600,022, 1 gene: EZH2P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 210 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:54,723,499–56,181,652, 32 genes, copy number 8–13: EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A, BTF3P5, RNU6-775P, RNU6-221P, RNU6-634P, CFAP36, PPP4R3B, AC015982.1, AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813.
- chr2:56,173,534–56,185,870, 1 gene, copy number 8: AC007743.1.
- chr2:73,986,404–74,108,176, 1 gene, copy number 7 (within-gene range 6–7): TET3.
- chr2:74,120,680–76,698,996, 83 genes, copy number 7 (broad region; genes not listed).
- chr2:76,772,909–76,773,045, 1 gene, copy number 7: RNA5SP98.
- chr6:89,560,875–90,587,072, 20 genes, copy number 7: AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7.
- chr8:138,588,235–138,914,041, 1 gene, copy number 7 (within-gene range 4–7): COL22A1.
- chr17:26,981,694–28,404,049, 71 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,014. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
